Surgical pathology report (de-identified scan), TCGA case TCGA-IE-A4EK, project TCGA-SARC (Sarcoma), tissue source site ABS - IUPUI, specimen TCGA-IE-A4EK-01A (Primary Tumor).

[page 1 of 3]
Operative Procedure:

Right laparoscopic retroperitoneal mass excision

Pre-Operative Diagnosis:

Leiomyosarcoma retroperitoneal

Post-Operative Diagnosis:

Same

Specimen Received:

A: Right kidney and retroperitoneal sarcoma (FS)

B: Paracaval lymph node

Final Pathologic Diagnosis:

A. Retroperitoneal mass and right kidney, resection:

Leiomyosarcoma, low grade. Please see cancer synoptic report.

Procedure: Radical resection

Tumor site: Retroperitoneal mass at the renal hilum

Tumor size: 6.5 cm (greatest dimension)

Macroscopic extent of tumor: Retroperitoneal

Histologic type: Leiomyosarcoma

Mitotic rate: 3/10 high-power fields (HPF)

Necrosis: Not identified

Histologic grade: low

Margins: Margins focally positive for sarcoma

ICD-O-3

leiomyosarcoma, nos 8890/3

ccof Site: retroperitoneum C48.0

Path: kidney, nos C64.9

hw
9/25/12

Pathologic staging (pTNM)

TNM descriptors:

Primary tumor (pT): pT1b

Regional lymph nodes (pN): pN0

Number examined: 9 (part B)

Number involved: 0

Distant metastasis (pM): pMX#

Additional pathologic findings: Tumor involves the renal vein.

Ureteral and renal blood vessel margins negative for tumor. Benign renal parenchyma with no significant pathologic change.

Ancillary studies

None

B. Lymph nodes, paracaval, lymph node dissection:

Nine lymph nodes, negative for malignancy (0/9).

[page 2 of 3]
The examination of this case material and the preparation of this report were performed by the staff pathologist.

Intraoperative Consult Diagnosis:

FSA1: Ureter margin:

Negative for tumor.

FSA2: Mass with soft tissue margin:

Leiomyosarcoma, less than 1 mm to soft tissue margin.

FSA3: Vascular margin:

Negative for tumor on margin; grossly tumor invades to renal vein.

F/S TAT: 40 mins.

Gross Description:

Received are two containers each labeled with the patient's name.

Part A is received fresh for intraoperative frozen section diagnosis and additionally labeled "right kidney and retroperitoneal sarcoma." The specimen consists of a 1,230 g radical nephrectomy specimen with abundant attached fat. It has overall dimensions of 26.7 x 14.8 x 13.7 cm. The specimen is remarkable for a firm, somewhat well-circumscribed extrarenal mass at the renal hilum that is 6.5 x 5.0 x 4.5 cm. This lesion grossly invades the renal vein. The ureter margin is identified and submitted as FSA1. This remnant is transferred and submitted in its entirety in cassette A1. A section of the mass is submitted for frozen section diagnosis as FSA2 to include its relationship to the inked soft tissue margin. This is resubmitted for permanent in cassette A2. The vascular margin is taken and submitted as FSA3 for frozen section diagnosis. The remnant is transferred and submitted in its entirety in cassette A3. The cut surface of the mass is white-tan and fleshy with a vaguely nodular appearance. A gross photograph of the lesion invading into the renal vein is taken. Further examination of the mass reveals no definitive invasion into the renal parenchyma proper. The kidney is now bivalved to reveal uninvolved renal parenchyma with well-defined corticomedullary junction. No identifiable lesions are seen within the renal parenchyma proper, however there is a single 1.0 x 1.2 x 0.4 cm, thin-walled cystic structure identified. No other grossly remarkable structures are identified. Representative sections are submitted as follows:

A4-8 multiple representative sections of mass to include relationship to the inked margin and renal vessels;

A9 renal vessels at renal sinus;

A10-12 multiple representative sections of renal parenchyma from upper to lower pole.

Careful examination through the attached fat reveals no adrenal gland present.

Part B is additionally labeled "paracaval lymph nodes" and consists of multiple probable lymph nodes that are submitted in cassettes B1-3.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

[page 3 of 3]
END OF REPORT

Taken:

Gender: M

Diagnostic Discrepancy		

pw
9/18/12

Source: NCI Genomic Data Commons file bd1da132-e80b-4de7-999b-f36a192b853f (TCGA-IE-A4EK.DAB727C8-7E36-485A-8BC3-D37CCCC3EF72.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).